Somatic mutation profile of tumor specimen TCGA-4K-AA1I-01A (aliquot TCGA-4K-AA1I-01A-11D-A435-10) from TCGA case TCGA-4K-AA1I, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 26.5 years (9,679 days).
Specimen TCGA-4K-AA1I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee1c7967-29ca-4c7c-9314-d6242ea5122a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4K-AA1I-10A (Blood Derived Normal), aliquot TCGA-4K-AA1I-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51a9ccb8-70e0-443d-bf1b-f1a696cf2b79

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERC1 | c.1907G>C p.R636T (on ENST00000360905 / NM_178040.4; = p.R608T on NM_178039.4) | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs200296939; called by muse, mutect2
- PKHD1L1 | c.10391A>G p.Y3464C | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs937897372; called by muse, mutect2
- ALDOB | c.982T>G p.F328V | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- CABS1 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNASE2B | c.815G>C p.R272T | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AARS2 | c.2847C>T p.H949= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV55115725; called by muse, mutect2
- ADPGK | c.1353A>G p.V451= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- DDIT4 | c.504C>T p.S168= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- LPA | c.5773C>T p.L1925= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- C1QTNF6 | c.289+812G>A | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
